Surgical pathology report (de-identified scan), TCGA case TCGA-WJ-A86L, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Greenville Health System, specimen TCGA-WJ-A86L-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGY EXAMINATION

PATIENT NAME: [REDACTED]

MED. REC. #: [REDACTED]

SOC. SEC. #: [REDACTED]

GENDER: [REDACTED]

ACCOUNT #: [REDACTED]

CLIENT: [REDACTED]

PHYSICIAN: [REDACTED]

ADDITIONAL: [REDACTED]

COPY TO/NOTES: [REDACTED]

Page 1 of 2

SPECIMEN(S) RECEIVED:

A: Segment 6 partial liver resection

B: Gallbladder

CLINICAL DATA/HISTORY:

HCC on biopsy. No known hepatitis or alcohol history. [REDACTED] hepatocellular carcinoma, high-grade with clear cells and giant cell features. Cystic lesion of gallbladder plus near hepatic resection for HCC.

FINAL PATHOLOGIC DIAGNOSIS:

A. LIVER, SEGMENT 6, PARTIAL RESECTION:

- MODERATELY DIFFERENTIATED HEPATOCELLULAR CARCINOMA, WITH CLEAR CELL AND GIANT CELL FEATURES. 95% 5%
- MARGIN NEGATIVE FOR MALIGNANCY.
- SEE SYNOPTIC REPORT AND COMMENT.

B. GALLBLADDER, CHOLECYSTECTOMY:

- BENIGN SIMPLE CYST.
- BENIGN GALLBLADDER WITH MINIMAL CHRONIC INFLAMMATION.

SYNOPTIC REPORT:

- SPECIMEN: LIVER AND GALLBLADDER.
- PROCEDURE: PARTIAL HEPATECTOMY.
- TUMOR SIZE: 3.5 CM IN GREATEST DIMENSION.
- TUMOR FOCALITY: SOLITARY (SEGMENT 6).
- HISTOLOGIC TYPE: HEPATOCELLULAR CARCINOMA.
- HISTOLOGIC GRADE: G2 (MODERATELY DIFFERENTIATED).
- TUMOR EXTENSION: TUMOR CONFINED TO LIVER.
- MARGINS: PARENCHYMAL MARGIN UNINVOLVED BY INVASIVE CARCINOMA.
- LYMPHOVASCULAR INVASION:
- MACROSCOPIC VENOUS INVASION: NOT IDENTIFIED.
- MICROSCOPIC INVASION: NOT IDENTIFIED.
- PATHOLOGIC STAGING: pT1
NO NODES SUBMITTED.

ICD O-3
Carcinoma, hepatocellular,
clear cell type 8310/3
Site Liver NOS C22.0
4/4/14

COMMENT: The background liver is non-cirrhotic and without any apparent fibrosis. The case was reviewed
Consultant: Dr. [REDACTED]

GROSS DESCRIPTION:

[page 2 of 2]
A. Segment 6 partial liver resection: Received fresh labeled, "segment 6 partial liver resection," is an 85-gram lobe of liver measuring 7 x 7 x 6 cm. The surface of the liver is faintly bosselated. The resection margin is marked with green ink, and the specimen is serially sectioned revealing an ill-defined tan-white soft mass measuring 3.5 x 2.8 x 2.5 cm. The mass lies 0.7 cm from the closest resection margin and within 0.1 cm of the serosal surface of the liver. The remaining cut surfaces shows a grossly normal brown liver parenchyma. Representative sections of the mass and normal liver are submitted for tissue banking. Gross photographs of the intact and sectioned specimen are taken. Representative sections of the specimen are submitted for permanent section: A1) Mass and serosal surface. A2) Mass at closest margin. A3-A4) Mass. A5) Nonneoplastic liver.

B. Gallbladder: Received in formalin labeled "Gallbladder" and consists of an intact gallbladder measuring 10 x 4 cm. The cystic duct margin is marked with yellow ink and is shaved and submitted en face. The gallbladder serosa is purple-tan, smooth and glistening. On the hepatic aspect of the gallbladder near the serosa is a raised soft cyst-like area measuring 0.5 cm in greatest dimension. This area is overmarked with green ink. The gallbladder mucosa is tan and velvety with no distinct masses, polyps, or plaques. The gallbladder wall has an average thickness of 0.2 cm. The cystic duct is nondilated. No gallstones are identified with the gallbladder lumen or specimen container. Representative sections including the cyst-like area in its entirety are submitted. B1) Cystic duct and random sections. B2) Cyst-like area.

MICROSCOPIC DESCRIPTION:

A. Sections show a nodular mass with areas of fibrous septation. The nodules are composed of sheets and focal trabecular arrangements of atypical cells. The mostly polygonal cells show marked variability in size. There are many very large cells with bizarre nuclei. Most of the cells show clear cytoplasm with distinct cell borders. In the more trabecular areas, the cells are smaller with more eosinophilic cytoplasm. Mitotic figures, including atypical ones, are common. The parenchymal resection margin is negative for tumor. No lymphovascular invasion is seen. The tumor abuts, but does not penetrate, the liver capsule. The hepatic parenchyma away from the mass shows a minimal lymphocytic infiltrate of the portal tracts. No notable fibrosis is seen by H&E. There is no suggestion of nodularity. No lobular activity is appreciated. Many of the hepatocytes have brown granular pigment.

B. Along the serosal surface, adjacent to a minimal amount of hepatic parenchyma, is a thin, fibrous cyst wall which is lined by a single layer of low cuboidal to flattened, bland epithelial cells. The gallbladder mucosa shows a minimal lymphocytic infiltrate. There is no dysplasia or malignancy.

95% clear cell.

OK to process

11/5/13

Diagnostic Discrepancy	95% clear 5% gran	✓
Prior to Diagnosis History		✓
Case is (r/r/c):		

Source: NCI Genomic Data Commons file 0402b1b5-4185-4165-8703-90b2a5363405 (TCGA-WJ-A86L.2C93F65E-88FD-405F-86F1-0E35C7F46DC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).